TARGET case TARGET-10-PASFGA — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bb17afc6-48b8-56fe-aeb8-3470f6772974

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 14 years; Vital status: Dead; Days to death: 1,482 days (4.1 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 14.2 years (5,176 days); Year of diagnosis: 2008; Days to last follow up: 1,482 days (4.1 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (1 entry)
- Days to follow up: 1,482 days (4.1 years); Days to first event: 1,482 days (4.1 years); First event: Death; Year of follow up: 2012.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 3.1 ×10³/µL.
- Day 8: Bone Marrow blast count 2%; Minimal Residual Disease (Flow Cytometry) 0.2%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0.0081%.

Biospecimens (8 samples)
- Sample TARGET-10-PASFGA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PASFGA-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
- Samples TARGET-10-PASFGA-60.11C, TARGET-10-PASFGA-60.1C, TARGET-10-PASFGA-60.3C, TARGET-10-PASFGA-60.5C, TARGET-10-PASFGA-60.7C, TARGET-10-PASFGA-60.9C (6 with the same recorded description): Sample type: Primary Xenograft Tissue; Tissue type: Tumor; Tumor descriptor: Xenograft.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Xenografts_20230727.xlsx:
- Overall Survival Time in Days: 1482
- WBC at Diagnosis: 3.1
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 8: 0.2
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.0081
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 2
- BMA Blasts Day 29: 0
- Karyotype: 31,X,+Y,+5,+9,add(9)(p13),der(10)t(9;10)(p13;p15),+11,+14,+19,+21[6]/62,idemx2,-5,-add(9)(p13),-add(9)(p13),+der(9)t(9;13)(p13;q22)inv(9)(q13q34)x2,+10,+10,-der(10)t(9;10),-der(10)t(9;10),-11,-14,+18[5]/72,(33,X,+Y,+5,+8,+9,der(9)t(9;13)(p13;q22)inv(9)(q…
- Down Syndrome: No
- DNA Index: 0.694
- Alternate Therapy: Chemotherapy; Transplant
- Cell of Origin: B Cell ALL
